Somatic mutation profile of tumor specimen fd4edc52-09ef-4b01-be7c-f23f05 (aliquot fd4edc52-09ef-4b01-be7c-f23f05_D6_1) from CPTAC case 14CO003, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen fd4edc52-09ef-4b01-be7c-f23f05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd3d2143-57b3-4588-ae53-78b83aea3a30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 79cabe71-f083-48ec-9b50-0c97a3 (Blood Derived Normal), aliquot 79cabe71-f083-48ec-9b50-0c97a3_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36d3ceab-6440-4980-93a9-b30283a0568d

The open-access MAF lists 1,146 somatic variants for this specimen: 785 protein-altering or splice-affecting, 227 silent, 134 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 527, Silent 227, Frame Shift Del 157, Intron 72, Frame Shift Ins 35, Nonsense Mutation 28, 3'UTR 20, In Frame Del 14, 5'Flank 12, Splice Region 12, 5'UTR 12, RNA 12.

Variants (750 of 1,146; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGL | c.4221del p.K1407Nfs*8 | Frame Shift Del (DEL) | VAF 38/110 reads (35%) | catalogued as rs786204655; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 77/267 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- LMNA | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 147/463 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs58932704, CM990813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MKRN3 | c.482dup p.A162Gfs*15 | Frame Shift Ins (INS) | VAF 81/279 reads (29%) | catalogued as rs763195944; ClinVar: pathogenic; called by mutect2, varscan2
- PCNT | c.2728C>T p.Q910* | Nonsense Mutation (SNP) | VAF 95/337 reads (28%) | catalogued as rs869312917, CM1515031; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SOX9 | c.499_501del p.K167del | In Frame Del (DEL) | VAF 106/374 reads (28%) | hotspot (GDC flag); called by pindel, varscan2
- TGFB2 | c.821del p.N274Tfs*10 | Frame Shift Del (DEL) | VAF 27/85 reads (32%) | catalogued as rs863223796; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCA2 | c.4970C>T p.S1657L (on ENST00000614293; = p.S1627L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs749362777; called by muse, mutect2, varscan2
- ABCC12 | c.1236+2T>C p.X412_splice | Splice Site (SNP) | VAF 39/112 reads (35%) | catalogued as rs746792798; called by muse, mutect2, varscan2
- AC093323.1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as rs1366308182; called by muse, mutect2, varscan2
- ACSS3 | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.621); catalogued as rs138023854; called by muse, mutect2, varscan2
- ACTN3 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs371839154; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 34/58 reads (59%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM28 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs150820766; called by muse, mutect2, varscan2
- ADAMTS14 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 103/343 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.119); catalogued as rs146369407; called by muse, mutect2, varscan2
- ADAMTS7 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs372048232; called by muse, mutect2
- ADAMTSL1 | c.2894G>A p.R965H | Missense Mutation (SNP) | VAF 116/285 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs745675169, COSV65892023; called by muse, mutect2, varscan2
- ADCY5 | c.1567G>A p.V523I | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs760775723; called by muse, mutect2, varscan2
- ADGRV1 | c.15271del p.Y5091Tfs*7 | Frame Shift Del (DEL) | VAF 79/313 reads (25%) | catalogued as rs1435790810; called by mutect2, pindel, varscan2
- AF196969.1 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 84/270 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.08); catalogued as COSV52142310; called by muse, mutect2, varscan2
- AGAP3 | c.67del p.Q23Sfs*31 (on ENST00000622464; = p.Q59Sfs*31 on NM_031946.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs1554459038; called by mutect2, pindel
- AGBL5 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201033068; called by muse, mutect2, varscan2
- AL645922.1 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 150/510 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754021968; called by muse, mutect2, varscan2
- AMH | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.147); catalogued as rs866354654; called by muse, varscan2
- ANGEL1 | c.1457G>A p.G486D | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1378112882; called by muse, mutect2, varscan2
- ANGPT1 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52461151; called by muse, mutect2, varscan2
- ANKIB1 | c.2413A>G p.S805G | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as rs775363363, COSV56059204; called by muse, mutect2, varscan2
- ANKK1 | c.1096del p.L366Sfs*13 | Frame Shift Del (DEL) | VAF 73/300 reads (24%) | catalogued as rs755428982; called by mutect2, pindel, varscan2
- ANKRD34B | c.1247del p.P416Qfs*4 | Frame Shift Del (DEL) | VAF 33/119 reads (28%) | catalogued as rs779065930, COSV100103683; called by mutect2, pindel, varscan2
- AP3B2 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs773513637, COSV55608014; called by muse, mutect2, varscan2
- AP4B1 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs763842373, COSV56725261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APBA1 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV55230411; called by muse, mutect2, varscan2
- ARHGEF2 | c.2570G>A p.R857Q (on ENST00000361247 / NM_001162383.2; = p.R829Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs533748068; called by muse, mutect2, varscan2
- ARHGEF7 | c.524G>A p.R175Q (on ENST00000375741 / NM_001113511.2; = p.R154Q on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.666); catalogued as rs760717132; called by muse, mutect2, varscan2
- ARID5B | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | catalogued as rs201178069; called by mutect2, pindel, varscan2
- ARL14EP | c.266del p.N89Ifs*4 | Frame Shift Del (DEL) | VAF 41/154 reads (27%) | catalogued as rs1247324796; called by mutect2, varscan2
- ARMH2 | c.136del p.I46Sfs*20 | Frame Shift Del (DEL) | VAF 56/185 reads (30%) | catalogued as rs965020534; called by mutect2, pindel*
- ASIC4 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 162/546 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1246195746, COSV100761577; called by muse, mutect2, varscan2
- ATG9B | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763653289; called by muse, mutect2, varscan2
- ATP10A | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755143094, COSV63523111; called by muse, mutect2, varscan2
- ATP2B2 | c.2974G>A p.V992I (on ENST00000352432; = p.V958I on NM_001683.5) | Missense Mutation (SNP) | VAF 179/593 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs765963921, COSV59495098; called by muse, mutect2, varscan2
- ATP6V1E2 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 83/253 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as rs150480219, COSV104403651; called by muse, mutect2, varscan2
- ATXN7 | c.2130T>A p.S710R | Missense Mutation (SNP) | VAF 55/363 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs755625089; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 51/198 reads (26%) | catalogued as rs35951843; called by mutect2, varscan2
- B4GALT6 | c.875_877del p.G292del | In Frame Del (DEL) | VAF 15/47 reads (32%) | catalogued as rs1156983701; called by pindel, varscan2
- BAIAP2L2 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs776528588, COSV57636774; called by muse, mutect2, varscan2
- BARHL2 | c.376del p.Q126Sfs*18 | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | catalogued as rs747119215; called by mutect2, pindel, varscan2
- BCL2L12 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as rs1459792321; called by muse, mutect2, varscan2
- BEX3 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100244358; called by muse, mutect2, varscan2
- BICRA | c.3052G>A p.A1018T | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs1336008568, COSV101194246; called by muse, mutect2, varscan2
- BICRA | c.4363G>A p.A1455T | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs1200561643; called by muse, mutect2, varscan2
- BLZF1 | c.488del p.K163Sfs*18 | Frame Shift Del (DEL) | VAF 33/132 reads (25%) | catalogued as COSV61394597; called by mutect2, pindel, varscan2
- BMP2 | c.231del p.Y78Tfs*3 | Frame Shift Del (DEL) | VAF 119/397 reads (30%) | catalogued as COSV66577890; called by mutect2, pindel, varscan2
- BOC | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 18/87 reads (21%) | catalogued as rs1038611376, COSV99848041, COSV99848956; called by muse, mutect2, varscan2
- BRAF | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as rs547693139, COSV56159745; called by muse, mutect2, varscan2
- BRCA2 | c.7021C>T p.R2341C | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs41293505; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- BRD3 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs780729968, CM161417, COSV100325357, COSV57707593; called by muse, mutect2, varscan2
- BTBD7 | c.2201G>A p.R734H | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs200930615; called by muse, mutect2, varscan2
- C17orf107 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.029); catalogued as rs1567637854; called by muse, mutect2, varscan2
- C17orf97 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.788); catalogued as rs1043736856, COSV64077511; called by muse, mutect2, varscan2
- C4orf17 | c.17del p.P6Rfs*19 | Frame Shift Del (DEL) | VAF 22/130 reads (17%) | catalogued as rs1391156280; called by mutect2, pindel, varscan2
- CAB39L | c.285del p.D96Mfs*2 | Frame Shift Del (DEL) | VAF 31/143 reads (22%) | catalogued as COSV61714509; called by mutect2, pindel, varscan2
- CACNA1G | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1335556091, COSV61720237; called by muse, mutect2, varscan2
- CACNA1H | c.6570del p.C2191Afs*26 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs760298114; called by pindel, varscan2
- CACNG1 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs555548756; called by muse, mutect2, varscan2
- CACNG2 | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 39/468 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV55638951; called by muse, mutect2
- CALR | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 111/325 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57139832; called by muse, mutect2, varscan2
- CARD9 | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 140/577 reads (24%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as rs1045323623; called by muse, mutect2, varscan2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 25/76 reads (33%) | catalogued as rs770159446; called by mutect2, varscan2
- CASKIN2 | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs369531665; called by muse, mutect2, varscan2
- CASP8 | c.1286T>C p.L429P (on ENST00000432109 / NM_033355.3; = p.L446P on NM_001228.4) | Missense Mutation (SNP) | VAF 41/361 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51848774, COSV51859047; called by muse, mutect2, varscan2
- CBWD6 | c.884A>G p.Q295R | Missense Mutation (SNP) | VAF 37/372 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.823); catalogued as rs1244037626; called by muse, mutect2, varscan2
- CCDC175 | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1299084960, COSV54200625; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC54 | c.415_417del p.K139del | In Frame Del (DEL) | VAF 30/134 reads (22%) | catalogued as rs1346332024; called by pindel, varscan2
- CCNG2 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as rs371620068; called by muse, mutect2, varscan2
- CCR1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs747244913, COSV56121663; called by muse, mutect2, varscan2
- CD276 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs543666880; called by muse, mutect2, varscan2
- CDC23 | c.483del p.K161Nfs*47 | Frame Shift Del (DEL) | VAF 15/75 reads (20%) | catalogued as COSV67508331; called by mutect2, pindel, varscan2
- CDK9 | c.627dup p.I210Hfs*2 | Frame Shift Ins (INS) | VAF 28/142 reads (20%) | catalogued as rs755440676; called by mutect2, varscan2
- CELSR1 | c.5098G>A p.V1700M | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs768104018; called by muse, mutect2, varscan2
- CEMIP2 | c.3722G>A p.R1241Q | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs370944210; called by muse, mutect2, varscan2
- CEP290 | c.6869A>T p.N2290I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as CD075343; called by muse, mutect2, varscan2
- CES4A | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as rs748541136; called by muse, mutect2, varscan2
- CHIT1 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 81/298 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs749457823, COSV55146459; called by muse, mutect2, varscan2
- CLINT1 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764235760, COSV99753388; called by muse, mutect2, varscan2
- CLIP3 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1394561930, COSV62111881; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | catalogued as rs369752219; called by mutect2, varscan2
- CLPB | c.1291G>A p.V431I | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as rs777151336; called by muse, mutect2, varscan2
- CMTM5 | c.377del p.P126Rfs*55 | Frame Shift Del (DEL) | VAF 135/470 reads (29%) | catalogued as rs751921758; called by mutect2, pindel, varscan2
- CNDP2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as rs200002510, COSV60841041; called by muse, mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | catalogued as rs748995811; called by mutect2, varscan2
- COL16A1 | c.2714C>T p.P905L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765679339; called by muse, mutect2, varscan2
- COL5A3 | c.2951del p.G984Afs*10 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs950356700; called by mutect2, pindel, varscan2
- COMMD8 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as rs1202544248; called by muse, mutect2, varscan2
- CPXM2 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.249); catalogued as rs962374194; called by muse, mutect2, varscan2
- CRB2 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753791463, COSV63504880; called by muse, mutect2, varscan2
- CST1 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 54/196 reads (28%) | catalogued as rs756924682; called by mutect2, varscan2
- CT47B1 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs749974682; called by muse, mutect2, varscan2
- CTR9 | c.3230G>A p.R1077Q | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs758492695, COSV63728397; called by muse, mutect2, varscan2
- CUBN | c.4639C>T p.R1547C | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs375920680; called by muse, mutect2, varscan2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs772257590; called by mutect2, varscan2
- CYC1 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs764532121; called by muse, mutect2
- DAB2IP | c.3001C>T p.R1001C (on ENST00000408936; = p.R973C on NM_032552.3) | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760472375; called by muse, varscan2
- DACT3 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs768322728, COSV56260949; called by muse, mutect2, varscan2
- DCAF12L2 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV63584420; called by muse, mutect2
- DCAF12L2 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100758666; called by muse, mutect2, varscan2
- DCAF5 | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs1387429322; called by muse, mutect2, varscan2
- DCLK3 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.088); catalogued as rs768535138; called by muse, mutect2, varscan2
- DDX31 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.119); catalogued as rs778619874, COSV60138749; called by muse, mutect2
- DDX39A | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs775269512, COSV54390780; called by muse, mutect2, varscan2
- DENND4C | c.5044G>A p.V1682M (on ENST00000434457 / NM_001330640.2; = p.V1633M on NM_017925.7) | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.595); catalogued as rs370968840; called by muse, mutect2, varscan2
- DERA | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); catalogued as rs754049202, COSV70775185; called by muse, mutect2, varscan2
- DIP2A | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs781413516; called by muse, mutect2, varscan2
- DISC1 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 173/595 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs769316063; called by muse, mutect2, varscan2
- DLAT | c.342del p.E115Rfs*10 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs782180715; called by mutect2, varscan2
- DLGAP4 | c.1910del p.P637Qfs*6 | Frame Shift Del (DEL) | VAF 56/189 reads (30%) | catalogued as COSV59415552; called by mutect2, pindel, varscan2
- DNAH10 | c.8569C>T p.R2857C (on ENST00000409039; = p.R2796C on NM_207437.3) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs951475672; called by muse, mutect2, varscan2
- DNAH17 | c.8891C>T p.A2964V | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760238543, COSV67756311; called by muse, mutect2, varscan2
- DNAH3 | c.2504C>T p.A835V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as rs748218982, COSV54544947; called by muse, mutect2, varscan2
- DNAH7 | c.9887C>T p.A3296V | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs144753545; called by muse, mutect2, varscan2
- DNAJB9 | c.19A>G p.I7V | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140430481; called by muse, mutect2, varscan2
- DNAJC25 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 27/84 reads (32%) | catalogued as rs749436855, COSV57957784; called by muse, mutect2, varscan2
- DOCK2 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1487304870, COSV56943483; called by muse, mutect2, varscan2
- DUS4L | c.869C>T p.T290I | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs1276598445; called by muse, mutect2
- E2F7 | c.2216C>T p.P739L | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs371572509; called by muse, mutect2, varscan2
- ELOVL5 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.279); catalogued as rs367553728; called by muse, mutect2, varscan2
- EME1 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.599); catalogued as rs201414369; called by muse, mutect2, varscan2
- EML5 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.449); catalogued as rs766756140, COSV61345662; called by muse, mutect2, varscan2
- EPHB6 | c.165+1del | Frame Shift Del (DEL) | VAF 92/451 reads (20%) | catalogued as rs771807343; called by mutect2, pindel, varscan2
- EPHX2 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 95/249 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs770615757, COSV66844337; called by muse, mutect2, varscan2
- EPN1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779010791, COSV50045564; called by muse, mutect2, varscan2
- EPN2 | c.1408del p.T470Qfs*5 | Frame Shift Del (DEL) | VAF 38/113 reads (34%) | catalogued as rs756461692; called by mutect2, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 30/89 reads (34%) | catalogued as rs768793415; called by mutect2, varscan2
- ETFDH | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as rs989125087, CM1313473, COSV100306676; called by muse, mutect2, varscan2
- EXD3 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs781179055, COSV59805280; called by muse, mutect2, varscan2
- EXD3 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs528218403, COSV59807191; called by muse, mutect2, varscan2
- EXOSC5 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199702542; called by muse, mutect2, varscan2
- FAM131B | c.451A>G p.M151V | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1219615035; called by muse, mutect2, varscan2
- FAN1 | c.34del p.R12Gfs*45 | Frame Shift Del (DEL) | VAF 19/86 reads (22%) | catalogued as rs752820596; called by mutect2, pindel, varscan2
- FAT1 | c.5566C>T p.R1856C | Missense Mutation (SNP) | VAF 24/255 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs576312211; called by muse, mutect2
- FLG | c.11441G>A p.R3814H | Missense Mutation (SNP) | VAF 246/827 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs746397911, COSV64236909; called by muse, mutect2, varscan2
- FLG | c.325A>G p.K109E | Missense Mutation (SNP) | VAF 80/261 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as COSV64244013; called by muse, mutect2, varscan2
- FOXD4L1 | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 261/800 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.27); catalogued as rs762518950; called by muse, varscan2
- FOXH1 | c.937del p.V313Wfs*15 | Frame Shift Del (DEL) | VAF 64/242 reads (26%) | catalogued as COSV56761013; called by mutect2, pindel, varscan2
- FRMPD4 | c.2711C>T p.S904L | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs751943219, COSV66215063; called by muse, mutect2, varscan2
- GBP2 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs766490853; called by muse, mutect2, varscan2
- GEM | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 28/114 reads (25%) | catalogued as rs762667312; called by muse, mutect2, varscan2
- GEMIN8 | c.473-2del p.X158_splice | Splice Site (DEL) | VAF 53/179 reads (30%) | catalogued as COSV60551224; called by mutect2, pindel, varscan2
- GFRA2 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs765796593, COSV60780558; called by muse, mutect2, varscan2
- GJA4 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 122/396 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.028); catalogued as rs1341828138; called by muse, mutect2, varscan2
- GLI2 | c.4094G>A p.R1365H (on ENST00000361492 / NM_001374353.1; = p.R1382H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs200080112; ClinVar: likely benign; called by muse, mutect2, varscan2
- GLI3 | c.4564del p.A1522Pfs*2 | Frame Shift Del (DEL) | VAF 123/533 reads (23%) | catalogued as CD050883; called by mutect2, pindel, varscan2
- GNAS | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as rs545306394, COSV100006150; ClinVar: not provided; called by muse, mutect2, varscan2
- GOLGA6B | c.1698A>G p.R566= | Splice Region (SNP) | VAF 66/660 reads (10%) | catalogued as rs1422331292; called by muse, mutect2
- GOT1L1 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs1314542319; called by muse, mutect2, varscan2
- GPAM | c.2234C>A p.P745H | Missense Mutation (SNP) | VAF 86/274 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV62080976; called by muse, mutect2, varscan2
- GPNMB | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs142450741; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 46/71 reads (65%) | catalogued as rs760757380; called by mutect2, varscan2
- GSTA2 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771389883, COSV101534064; called by muse, mutect2, varscan2
- GTF2F1 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 37/295 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs142604322; called by muse, mutect2, varscan2
- HCRTR1 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 109/362 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs757082425, COSV65485370; called by muse, mutect2, varscan2
- HDHD3 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 80/366 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs747271508, COSV53056680; called by muse, mutect2, varscan2
- HECTD1 | c.3013C>T p.R1005C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV67950042; called by muse, mutect2, varscan2
- HERC1 | c.6935_6937del p.G2312del | In Frame Del (DEL) | VAF 38/134 reads (28%) | catalogued as rs932955902; called by pindel, varscan2
- HGS | c.1447del p.A483Rfs*2 | Frame Shift Del (DEL) | VAF 25/99 reads (25%) | catalogued as rs1555699517, COSV100230656; called by mutect2, pindel, varscan2
- HHIPL1 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1165634547, COSV58091202; called by muse, mutect2
- HMCN1 | c.9545C>T p.T3182M | Missense Mutation (SNP) | VAF 125/308 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs765794058, COSV54878571; called by muse, mutect2, varscan2
- HOOK1 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.458); catalogued as rs762378621; called by muse, mutect2, varscan2
- HOXA2 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV99761238; called by muse, mutect2, varscan2
- HOXC9 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374611200; called by muse, mutect2, varscan2
- HTR3C | c.919del p.L307Sfs*12 | Frame Shift Del (DEL) | VAF 63/248 reads (25%) | catalogued as rs1394232956; called by mutect2, pindel, varscan2
- HUWE1 | c.9532C>T p.R3178W | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1556926625, COSV53340875; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 26/110 reads (24%) | catalogued as rs747841314; called by mutect2, varscan2
- ICAM3 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); catalogued as COSV99349353; called by muse, mutect2, varscan2
- IFNGR2 | c.469A>G p.I157V | Missense Mutation (SNP) | VAF 113/347 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as rs1487196634; called by muse, mutect2, varscan2
- IGLV1-51 | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 98/342 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1185771812; called by muse, mutect2, varscan2
- INPP5D | c.1253dup p.P419Sfs*27 (on ENST00000445964 / NM_001017915.3; = p.P418Sfs*27 on NM_005541.5) | Frame Shift Ins (INS) | VAF 23/106 reads (22%) | catalogued as rs759837481; called by mutect2, varscan2
- IRGC | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); catalogued as rs56159111, COSV54986117; called by muse, mutect2
- IRS2 | c.2359G>T p.A787S | Missense Mutation (SNP) | VAF 21/628 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.03); catalogued as rs1255254387; called by muse, mutect2
- IRX6 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 74/233 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as rs1379228156; called by muse, mutect2, varscan2
- ITPRID1 | c.3106del p.S1036Lfs*13 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | catalogued as rs35589779; called by mutect2, varscan2
- JADE3 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1355562695, COSV99509937; called by muse, mutect2, varscan2
- KCND3 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 105/344 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as rs755294522; called by muse, mutect2, varscan2
- KCNJ8 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 108/317 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764215606, COSV53717414; called by muse, mutect2, varscan2
- KCNK15 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 112/334 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs201484292, COSV65719784; called by muse, mutect2, varscan2
- KIAA0825 | c.2156C>T p.T719I | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1361911922; called by muse, mutect2, varscan2
- KIF7 | c.2360G>A p.R787H | Missense Mutation (SNP) | VAF 124/403 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs775204546; called by muse, mutect2, varscan2
- KLHL25 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 98/276 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs1310119684, COSV100563419; called by muse, mutect2, varscan2
- KRTAP2-4 | c.336dup p.C113Lfs*28 | Frame Shift Ins (INS) | VAF 48/218 reads (22%) | catalogued as rs1398468879; called by mutect2, pindel, varscan2
- LAMA1 | c.1789G>A p.V597I | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.193); catalogued as rs140625362; called by muse, mutect2, varscan2
- LAMA1 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs200626690; called by muse, mutect2, varscan2
- LATS2 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV66878494; called by muse, mutect2, varscan2
- LCT | c.4771G>T p.G1591C | Missense Mutation (SNP) | VAF 138/426 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV51551591; called by muse, mutect2, varscan2
- LHFPL5 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 187/537 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs755791421; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 49/164 reads (30%) | catalogued as rs775423572; called by mutect2, pindel, varscan2
- LIX1 | c.304T>C p.S102P | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs756406584; called by muse, mutect2, varscan2
- LMBR1L | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs758249833, COSV57266924; called by muse, mutect2, varscan2
- LPA | c.3047G>A p.R1016Q | Missense Mutation (SNP) | VAF 76/315 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV60300269, COSV60301484, COSV60312833; called by muse, mutect2, varscan2
- LRP8 | c.2813C>T p.P938L | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); catalogued as rs764136962, COSV60096714; called by muse, mutect2, varscan2
- LRRC30 | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 74/239 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.146); catalogued as COSV101274366; called by muse, mutect2, varscan2
- LRRC8C | c.1615C>T p.R539W | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64999161; called by muse, mutect2, varscan2
- LRRC8E | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 133/415 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs372842190; called by muse, mutect2, varscan2
- LRRTM3 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63663962; called by muse, mutect2, varscan2
- LSAMP | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754613210; called by muse, mutect2, varscan2
- LY6K | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs782114292; called by muse, mutect2, varscan2
- LY96 | c.22dup p.S8Ffs*10 | Frame Shift Ins (INS) | VAF 52/226 reads (23%) | catalogued as rs1234074626; called by mutect2, varscan2
- MAGEC1 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 134/447 reads (30%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.448); catalogued as rs764103583, COSV53568059; called by muse, varscan2
- MAGIX | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 163/577 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.095); catalogued as rs782047537; called by muse, varscan2
- MAN1A1 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.046); catalogued as rs367711162; called by muse, mutect2, varscan2
- MAN2B1 | c.1478G>A p.C493Y | Missense Mutation (SNP) | VAF 148/504 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55472457; called by muse, varscan2
- MAP7D1 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.647); catalogued as rs372899934; called by muse, mutect2, varscan2
- MARK2 | c.1714G>A p.A572T (on ENST00000402010 / NM_001039469.2; = p.A517T on NM_004954.5) | Missense Mutation (SNP) | VAF 114/365 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs746404079, COSV59282132; called by muse, mutect2, varscan2
- MASTL | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs185334476, COSV60910499; called by muse, mutect2, varscan2
- MBD6 | c.2345dup p.A783Sfs*10 | Frame Shift Ins (INS) | VAF 16/54 reads (30%) | catalogued as rs746267361; called by mutect2, varscan2
- MBP | c.86dup p.R30Efs*5 | Frame Shift Ins (INS) | VAF 34/110 reads (31%) | catalogued as rs374687958; called by mutect2, varscan2
- MDH1B | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758996026, COSV100982176; called by muse, mutect2, varscan2
- MEGF11 | c.1832del p.P611Lfs*189 | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | catalogued as rs775071380; called by mutect2, pindel, varscan2
- MEIOB | c.1del p.M1? | Frame Shift Del (DEL) | VAF 26/75 reads (35%) | catalogued as rs756894401; called by mutect2, pindel, varscan2
- MFHAS1 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 117/340 reads (34%) | catalogued as COSV52284464; called by muse, mutect2, varscan2
- MGAT1 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 59/174 reads (34%) | PolyPhen benign (0.191); catalogued as rs759196211, COSV100286874; called by muse, mutect2, varscan2
- MLXIPL | c.86C>A p.S29* | Nonsense Mutation (SNP) | VAF 49/235 reads (21%) | catalogued as COSV57668772; called by muse, mutect2, varscan2
- MMP23B | c.1111G>A p.V371M | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as rs1432443058; called by muse, mutect2, varscan2
- MOK | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375778084; called by muse, mutect2, varscan2
- MRPL10 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs781472477, COSV50111164; called by muse, mutect2, varscan2
- MRPL38 | c.771del p.F258Sfs*54 | Frame Shift Del (DEL) | VAF 36/113 reads (32%) | catalogued as rs758439223; called by mutect2, varscan2
- MUC16 | c.14291C>T p.P4764L | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs371360570; called by muse, mutect2, varscan2
- MUC4 | c.13903G>A p.V4635M (on ENST00000463781 / NM_018406.7; = p.V399M on NM_004532.6) | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.272); catalogued as rs111517228; called by muse, mutect2, varscan2
- MUC5AC | c.16417G>A p.A5473T | Missense Mutation (SNP) | VAF 86/307 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as rs774637339; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 50/155 reads (32%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYBBP1A | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs746733011, COSV54597043; called by muse, mutect2, varscan2
- MYH14 | c.4493G>A p.R1498H | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs576482145, COSV99224744; called by muse, mutect2, varscan2
- MYH7B | c.2132G>A p.R711Q | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as rs769215876, COSV99483278; called by muse, mutect2, varscan2
- MYO15A | c.793G>A p.G265S | Missense Mutation (SNP) | VAF 154/513 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs764355744, COSV52762587; called by muse, mutect2, varscan2
- MYO15A | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 173/571 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV99234004; called by muse, mutect2, varscan2
- MYO18A | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100571945; called by muse, mutect2, varscan2
- MYOM2 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755403026, COSV50704948; called by muse, mutect2, varscan2
- MYOZ1 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs767586169, COSV63771848; called by muse, mutect2, varscan2
- NBPF11 | c.2436G>C p.W812C | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.369); catalogued as rs1236763507; called by muse, mutect2, varscan2
- NCAPG2 | c.2992C>T p.H998Y | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV51989454; called by muse, mutect2, varscan2
- NDN | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs549529148, COSV100086387; called by muse, mutect2, varscan2
- NDST3 | c.1455C>A p.F485L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.803); catalogued as COSV56614464; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 24/81 reads (30%) | catalogued as rs747914168; called by mutect2, varscan2
- NECTIN2 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 97/275 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs545950313, COSV52977185; called by muse, mutect2, varscan2
- NELFB | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 80/288 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs757737702, COSV100546744; called by muse, mutect2, varscan2
- NID2 | c.3103del p.R1035Gfs*67 | Frame Shift Del (DEL) | VAF 50/218 reads (23%) | catalogued as COSV53499514; called by mutect2, pindel, varscan2
- NLN | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1423016963, COSV66765901; called by muse, mutect2, varscan2
- NLRP12 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 120/462 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs781341758, COSV60743424, COSV60751214; called by muse, mutect2, varscan2
- NLRP4 | c.1507C>A p.L503I | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.053); catalogued as COSV100016881; called by muse, mutect2, varscan2
- NLRP7 | c.2161C>T p.R721W (on ENST00000340844 / NM_206828.3; = p.R693W on NM_139176.3) | Missense Mutation (SNP) | VAF 91/260 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs104895525, CM094499; ClinVar: not provided; called by muse, mutect2, varscan2
- NMRK2 | c.35del p.N12Tfs*7 | Frame Shift Del (DEL) | VAF 32/111 reads (29%) | catalogued as COSV51455426; called by mutect2, pindel, varscan2
- NOL4L | c.396dup p.Y133Lfs*18 | Frame Shift Ins (INS) | VAF 32/130 reads (25%) | catalogued as rs751187638; called by mutect2, varscan2
- NOS1 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV57616898; called by muse, mutect2, varscan2
- NOTCH1 | c.2644G>A p.A882T | Missense Mutation (SNP) | VAF 172/737 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs767886377, COSV53056756; called by muse, mutect2, varscan2
- NPBWR1 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 101/352 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1286266756; called by muse, mutect2, varscan2
- NRXN2 | c.809C>G p.A270G | Missense Mutation (SNP) | VAF 67/249 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.013); catalogued as rs1351585896, COSV55461646; called by mutect2, varscan2
- NTNG1 | c.1402G>A p.D468N (on ENST00000370068 / NM_001113226.3; = p.D367N on NM_014917.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV64272617; called by muse, mutect2, varscan2
- NTRK3 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 116/350 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV100448531; called by muse, varscan2
- NWD1 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 105/358 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs144804746; called by muse, mutect2, varscan2
- OLFML2B | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 151/428 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771550649, COSV54198120; called by muse, mutect2, varscan2
- OR13C9 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 85/375 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1242841179; called by muse, mutect2, varscan2
- OR2J3 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 110/374 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs755458130, COSV65848628, COSV65848702; called by muse, mutect2, varscan2
- OR3A1 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 53/472 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs143631940; called by muse, mutect2, varscan2
- OR51E1 | c.466del p.A156Lfs*3 | Frame Shift Del (DEL) | VAF 53/196 reads (27%) | catalogued as rs1564877761; called by mutect2, pindel, varscan2
- OR51E2 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 92/269 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201945969, COSV67807056; called by muse, mutect2, varscan2
- OR51F1 | c.467T>C p.L156P | Missense Mutation (SNP) | VAF 22/319 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV58579646; called by muse, mutect2
- OR56A3 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 140/470 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs374842307, COSV99052017; called by muse, mutect2, varscan2
- OR6T1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 113/347 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs765590865, COSV100190091, COSV58307265; called by muse, mutect2, varscan2
- P2RX1 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 126/304 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377348733, COSV56653927; called by muse, mutect2, varscan2
- P2RY2 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as rs1241008063, COSV60775835; called by muse, mutect2
- PACRGL | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs183601092; called by muse, mutect2, varscan2
- PAPOLG | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.689); catalogued as rs768955041, COSV53181463; called by muse, mutect2, varscan2
- PAQR9 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 81/312 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100503949, COSV104415435, COSV61418264; called by muse, mutect2, varscan2
- PAX7 | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 100/299 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.362); catalogued as rs775613248, COSV104428094; called by muse, mutect2, varscan2
- PCDH17 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 104/428 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64973522; called by muse, mutect2, varscan2
- PCDH19 | c.3046G>A p.A1016T (on ENST00000373034 / NM_001184880.2; = p.A968T on NM_020766.3) | Missense Mutation (SNP) | VAF 111/397 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV55257182; called by muse, mutect2, varscan2
- PCDHB1 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 12/259 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs371501773; called by muse, mutect2
- PCDHB10 | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 126/351 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.182); catalogued as rs782290769, COSV53377610, COSV99505091; called by muse, mutect2, varscan2
- PCDHGA11 | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV53906668; called by muse, mutect2, varscan2
- PCNX2 | c.1856del p.K619Rfs*52 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | catalogued as COSV50784264; called by mutect2, pindel, varscan2
- PDGFRA | c.3050G>A p.G1017D | Missense Mutation (SNP) | VAF 42/376 reads (11%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.611); catalogued as COSV57277646; called by muse, mutect2, varscan2
- PDS5B | c.3537G>T p.M1179I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1324624529, COSV100221622; called by muse, mutect2, varscan2
- PDZD2 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as rs780255341, COSV56860068; called by muse, mutect2, varscan2
- PIEZO2 | c.3260C>T p.T1087M | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs759920772, COSV57428597; called by muse, mutect2, varscan2
- PKD1L1 | c.5554G>A p.A1852T | Missense Mutation (SNP) | VAF 106/429 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as rs1437361475; called by muse, mutect2, varscan2
- PKD1L3 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.403); catalogued as rs867378515, COSV58663338; called by muse, mutect2, varscan2
- PLEKHH1 | c.3263T>C p.V1088A | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs1196107573; called by muse, mutect2, varscan2
- PLEKHN1 | c.1342C>T p.R448* (on ENST00000379409; = p.R396* on NM_032129.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 43/133 reads (32%) | catalogued as rs774112267, COSV100379071; called by muse, mutect2, varscan2
- PLXNA3 | c.3640C>T p.R1214W | Missense Mutation (SNP) | VAF 93/314 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs782762047, COSV63756023; called by muse, mutect2, varscan2
- PLXNB2 | c.3946C>T p.L1316F | Missense Mutation (SNP) | VAF 91/282 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100834056; called by muse, mutect2
- PML | c.2386C>T p.R796C | Missense Mutation (SNP) | VAF 100/344 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs754836240, COSV51453363; called by muse, mutect2, varscan2
- PNPLA7 | c.3522del p.I1175Sfs*148 | Frame Shift Del (DEL) | VAF 27/120 reads (23%) | catalogued as rs761459630; called by mutect2, pindel, varscan2
- PNPLA7 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 40/170 reads (24%) | catalogued as COSV52995780; called by muse, varscan2
- POLR1F | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs1174465364; called by muse, mutect2, varscan2
- POU2F1 | c.11C>T p.P4L (on ENST00000541643 / NM_001365848.1; = p.P27L on NM_002697.4) | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.114); catalogued as rs1386619921; called by muse, mutect2, varscan2
- PPP1R26 | c.3161del p.G1054Afs*100 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | catalogued as rs1554733377; called by mutect2, pindel, varscan2
- PPP1R27 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs777965055, COSV57672687; called by muse, mutect2, varscan2
- PPP1R2B | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 163/513 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.666); catalogued as rs762425105, COSV70372972; called by muse, mutect2, varscan2
- PRC1 | c.1368dup p.Q457Tfs*16 | Frame Shift Ins (INS) | VAF 37/130 reads (28%) | catalogued as rs1231355293; called by mutect2, pindel, varscan2
- PREX1 | c.3536C>T p.S1179L | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs867828667; called by muse, mutect2, varscan2
- PRICKLE3 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV66235130; called by muse, mutect2, varscan2
- PROS1 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 66/268 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as rs769125007, COSV67776459; called by muse, mutect2, varscan2
- PROX1 | c.1780dup p.Y594Lfs*32 | Frame Shift Ins (INS) | VAF 26/103 reads (25%) | catalogued as COSV99799692; called by mutect2, varscan2
- PRRT4 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as rs1167578793; called by muse, mutect2, varscan2
- PRTN3 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.483); catalogued as rs756064884, COSV99311606; called by muse, mutect2, varscan2
- PSD | c.593del p.G198Afs*19 | Frame Shift Del (DEL) | VAF 45/159 reads (28%) | catalogued as COSV99194092; called by mutect2, pindel, varscan2
- PSMC5 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56738498; called by muse, mutect2, varscan2
- RAPGEF3 | c.2402G>A p.R801Q (on ENST00000389212; = p.R759Q on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs796826496; called by muse, mutect2, varscan2
- RAPGEF5 | c.418G>A p.V140I (on ENST00000401957 / NM_001367602.2; = p.V443I on NM_012294.5) | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs374412138; called by muse, mutect2, varscan2
- RASA3 | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 53/252 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.709); catalogued as rs765037785, COSV61866854; called by muse, mutect2, varscan2
- RASSF9 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 57/179 reads (32%) | catalogued as rs1053694318, COSV63432565; called by muse, mutect2, varscan2
- RBMX | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 27/146 reads (18%) | catalogued as rs1462288141, COSV100284920; called by muse, mutect2, varscan2
- RELB | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs755747339, COSV55513391; called by muse, mutect2, varscan2
- RET | c.2772del p.F924Lfs*22 | Frame Shift Del (DEL) | VAF 126/446 reads (28%) | catalogued as COSV60703037; called by mutect2, pindel, varscan2
- RIMS1 | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as rs1414432029, COSV53450436; called by muse, mutect2, varscan2
- RIOK3 | c.179+1G>A p.X60_splice | Splice Site (SNP) | VAF 23/65 reads (35%) | catalogued as rs373422920; called by muse, mutect2, varscan2
- RNF207 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 74/257 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs368957775; called by muse, mutect2, varscan2
- RNF25 | c.749del p.G250Efs*29 | Frame Shift Del (DEL) | VAF 24/132 reads (18%) | catalogued as rs746813141; called by mutect2, pindel, varscan2
- ROBO2 | c.2911G>A p.G971R | Missense Mutation (SNP) | VAF 79/290 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs201894179; called by muse, mutect2, varscan2
- ROCK2 | c.2669del p.K890Rfs*30 | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | catalogued as COSV59965414; called by mutect2, pindel, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPUSD4 | c.763_764del p.S255Lfs*31 | Frame Shift Del (DEL) | VAF 56/188 reads (30%) | catalogued as rs1419179521; called by pindel, varscan2
- RSBN1 | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs776315071; called by muse, mutect2, varscan2
- SCARA5 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 90/264 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs779607235, COSV57279459; called by muse, mutect2, varscan2
- SCARB1 | c.543G>T p.W181C | Missense Mutation (SNP) | VAF 174/482 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99909405; called by mutect2, varscan2
- SCN4A | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 88/269 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs374529559, COSV71126821; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SCP2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1442103564, COSV65260353, COSV65261606; called by muse, mutect2, varscan2
- SCUBE1 | c.2768G>A p.R923H | Missense Mutation (SNP) | VAF 104/338 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546345952, COSV62613113; called by muse, mutect2, varscan2
- SEC14L6 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as rs773354534; called by muse, mutect2, varscan2
- SEMA4A | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 86/261 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.424); catalogued as rs779154677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA4C | c.1975del p.L659Wfs*87 | Frame Shift Del (DEL) | VAF 29/296 reads (10%) | catalogued as rs1436989321; called by mutect2, pindel
- SETX | c.3755del p.G1252Dfs*9 | Frame Shift Del (DEL) | VAF 58/297 reads (20%) | catalogued as rs1275836821; called by mutect2, pindel, varscan2
- SH2B3 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1177556874, COSV100374599; called by muse, mutect2, varscan2
- SH2D3A | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs774103600, COSV55586336; called by muse, mutect2, varscan2
- SH2D3C | c.2351G>A p.R784H (on ENST00000314830 / NM_170600.3; = p.R627H on NM_005489.4) | Missense Mutation (SNP) | VAF 71/287 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs749026095; called by muse, mutect2, varscan2
- SIAH3 | c.344A>G p.Q115R | Missense Mutation (SNP) | VAF 116/406 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as rs752914271; called by muse, mutect2, varscan2
- SIGLEC12 | c.915dup p.T306Hfs*136 (on ENST00000291707 / NM_053003.4; = p.T188Hfs*136 on NM_033329.2) | Frame Shift Ins (INS) | VAF 35/116 reads (30%) | catalogued as rs758011625; called by mutect2, pindel, varscan2
- SIM1 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV99492728; called by muse, mutect2, varscan2
- SKOR2 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 174/570 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs1442842021; called by muse, mutect2, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC10A4 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs1420077514; called by muse, mutect2, varscan2
- SLC12A5 | c.2932G>A p.V978I (on ENST00000454036 / NM_001134771.2; = p.V955I on NM_020708.5) | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs748274754; called by muse, mutect2, varscan2
- SLC13A4 | c.1778T>G p.L593R | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765041687; called by muse, mutect2, varscan2
- SLC16A2 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 89/255 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.445); catalogued as COSV99330654; called by muse, mutect2, varscan2
- SLC23A1 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs754423492; called by muse, mutect2, varscan2
- SLC38A2 | c.1462G>A p.G488R | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.991); catalogued as rs764183704; called by muse, mutect2, varscan2
- SLC4A5 | c.3236del p.K1079Rfs*29 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | catalogued as rs778293501; called by mutect2, pindel, varscan2
- SLC66A1 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs1038094695, COSV64320598; called by muse, mutect2, varscan2
- SLITRK5 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 87/352 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as rs1404825112; called by muse, mutect2, varscan2
- SLK | c.2387G>A p.R796H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59824665; called by muse, mutect2, varscan2
- SMARCAD1 | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 103/334 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs768385881, COSV100758974, COSV62773721; called by muse, mutect2, varscan2
- SMG5 | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.778); catalogued as rs771353699, COSV62434915; called by muse, mutect2, varscan2
- SMURF2 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.934); catalogued as rs535944315; called by muse, mutect2, varscan2
- SND1 | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 67/313 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs539486991; called by muse, mutect2, varscan2
- SNX25 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs371336554; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 37/120 reads (31%) | catalogued as rs768873484; called by mutect2, varscan2
- SOS2 | c.2318A>G p.D773G | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV53563560; called by muse, mutect2, varscan2
- SOX7 | c.769del p.L257Wfs*14 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs1478777952; called by mutect2, pindel, varscan2
- SPNS2 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769429663; called by muse, mutect2, varscan2
- SPTBN2 | c.5066G>A p.R1689H | Missense Mutation (SNP) | VAF 81/604 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs764884402; called by muse, mutect2, varscan2
- SQSTM1 | c.632_634del p.P211del | In Frame Del (DEL) | VAF 168/666 reads (25%) | catalogued as rs747274001; called by pindel, varscan2
- SRRT | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1378118436; called by muse, mutect2, varscan2
- ST14 | c.751del p.D251Tfs*6 | Frame Shift Del (DEL) | VAF 97/336 reads (29%) | catalogued as COSV99598575; called by mutect2, pindel, varscan2
- STMN4 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99740949; called by muse, mutect2
- STOX2 | c.2660C>T p.P887L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as COSV100408206; called by muse, mutect2, varscan2
- SUFU | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 143/548 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201326378, COSV64016546; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SULF2 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 85/276 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.086); catalogued as rs763698817, COSV63418452; called by muse, mutect2, varscan2
- SUPT20HL1 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 97/357 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as rs779349438; called by muse, mutect2, varscan2
- SYCP2 | c.335A>G p.Q112R | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs576467891, COSV62766318; called by muse, mutect2, varscan2
- TACC2 | c.2347del p.Q783Rfs*32 | Frame Shift Del (DEL) | VAF 48/199 reads (24%) | catalogued as rs750901207; called by mutect2, pindel, varscan2
- TAF1D | c.281del p.K94Rfs*26 | Frame Shift Del (DEL) | VAF 31/92 reads (34%) | catalogued as rs746556335; called by mutect2, varscan2
- TAF1L | c.4126C>T p.R1376* | Nonsense Mutation (SNP) | VAF 140/564 reads (25%) | catalogued as rs781629508, COSV99644412; called by muse, mutect2, varscan2
- TAS2R4 | c.252dup p.V85Cfs*28 | Frame Shift Ins (INS) | VAF 44/249 reads (18%) | catalogued as rs746817338; called by mutect2, varscan2
- TBC1D16 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs758918595, COSV100187766; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 35/84 reads (42%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 93/345 reads (27%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- TBX6 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 61/203 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs202084430; called by muse, mutect2, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 48/150 reads (32%) | catalogued as rs745872748; called by mutect2, varscan2
- TCTA | c.130_132dup p.L44dup | In Frame Ins (INS) | VAF 85/334 reads (25%) | catalogued as rs764746241; called by mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 66/177 reads (37%) | catalogued as rs763321097; called by mutect2, varscan2
- TEK | c.2254C>A p.L752I | Missense Mutation (SNP) | VAF 154/554 reads (28%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as COSV101193200; called by muse, mutect2, varscan2
- TEX2 | c.2815C>T p.R939W (on ENST00000583097 / NM_001288733.2; = p.R946W on NM_018469.5) | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1327535633, COSV51983631; called by muse, mutect2, varscan2
- TFDP2 | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.003); catalogued as rs755075231; called by muse, mutect2, varscan2
- THEG | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765469573, COSV61074893; called by muse, mutect2, varscan2
- THOC6 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 94/314 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs751175080; called by muse, mutect2, varscan2
- TKTL1 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs142614631; called by muse, mutect2, varscan2
- TLNRD1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs774870171; called by muse, mutect2, varscan2
- TLR3 | c.2653C>T p.R885W | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774708574; called by muse, mutect2, varscan2
- TMA16 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs201147615; called by muse, mutect2, varscan2
- TMEM132B | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 111/342 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs764860749, COSV54758365, COSV54766311; called by muse, mutect2, varscan2
- TMEM190 | c.305+2C>T p.X102_splice | Splice Site (SNP) | VAF 61/207 reads (29%) | catalogued as rs762143109; called by muse, mutect2, varscan2
- TMEM201 | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 77/294 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1390591100, COSV61160823; called by muse, mutect2, varscan2
- TMEM64 | c.1097A>T p.N366I | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as rs201839000; called by muse, mutect2, varscan2
- TNC | c.6498C>T p.G2166= | Splice Region (SNP) | VAF 13/58 reads (22%) | catalogued as rs773223152, COSV60790747; called by mutect2, varscan2
- TNC | c.3925C>T p.R1309C | Missense Mutation (SNP) | VAF 22/701 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs975197014, COSV60786586; called by muse, mutect2
- TNFRSF1B | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 81/282 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs112914333; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 83/110 reads (75%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNRC6A | c.5465G>A p.R1822H | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs773351733; called by muse, mutect2, varscan2
- TNXB | c.6532C>T p.R2178W (on ENST00000647633; = p.R1931W on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/267 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs755808228, COSV104427349; called by muse, mutect2
- TONSL | c.3698C>T p.S1233L | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs782231158, COSV52871725; called by muse, mutect2, varscan2
- TPCN2 | c.1059G>T p.Q353H | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs370022048; called by muse, mutect2, varscan2
- TRAV25 | c.191dup p.L64Ffs*? | Frame Shift Ins (INS) | VAF 20/84 reads (24%) | catalogued as rs774036885; called by mutect2, varscan2
- TROAP | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 88/368 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.854); catalogued as rs543751573; called by muse, mutect2, varscan2
- TRPM1 | c.3547C>T p.R1183W | Missense Mutation (SNP) | VAF 124/430 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1369436827; called by muse, mutect2, varscan2
- TRPM2 | c.3229C>T p.R1077C | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200346541, COSV55969231; called by muse, mutect2, varscan2
- TSPAN7 | c.516del p.S173Afs*4 | Frame Shift Del (DEL) | VAF 114/367 reads (31%) | catalogued as rs752121179, COSV54531581; called by mutect2, pindel, varscan2
- TSSC4 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 91/316 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs11555996; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 24/94 reads (26%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.99767C>T p.S33256L (on ENST00000591111; = p.S25832L on NM_003319.4) | Missense Mutation (SNP) | VAF 133/422 reads (32%) | PolyPhen possibly damaging (0.683); catalogued as rs373446383; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.55133_55135del p.E18378del (on ENST00000591111; = p.E10954del on NM_003319.4) | In Frame Del (DEL) | VAF 55/174 reads (32%) | catalogued as rs886055257; called by pindel, varscan2
- UBALD2 | c.121-3C>T | Splice Region (SNP) | VAF 31/94 reads (33%) | catalogued as rs780414871; called by muse, mutect2, varscan2
- UBE2Q2 | c.435_437dup p.E146dup | In Frame Ins (INS) | VAF 23/74 reads (31%) | catalogued as rs756670016; called by mutect2, varscan2
- UCK1 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 73/271 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs774541508, COSV61227633; called by muse, mutect2, varscan2
- UGT2B28 | c.462del p.P155Lfs*33 | Frame Shift Del (DEL) | VAF 49/172 reads (28%) | catalogued as rs1340116028; called by mutect2, pindel, varscan2
- USH2A | c.12278C>T p.T4093I | Missense Mutation (SNP) | VAF 105/343 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as rs758557130; called by muse, mutect2, varscan2
- USP11 | c.1789C>T p.R597C (on ENST00000218348; = p.R554C on NM_001371072.1) | Missense Mutation (SNP) | VAF 80/343 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99511197; called by muse, mutect2, varscan2
- UTP20 | c.7396+4_7396+7del p.X2466_splice | Splice Site (DEL) | VAF 16/50 reads (32%) | catalogued as rs779454470; called by pindel, varscan2
- VASH2 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as rs1239270181; called by muse, mutect2, varscan2
- VEPH1 | c.1513del p.E505Sfs*12 | Frame Shift Del (DEL) | VAF 65/223 reads (29%) | catalogued as COSV62876697; called by mutect2, pindel, varscan2
- VPS9D1 | c.947del p.P316Rfs*93 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | catalogued as rs1452701539; called by mutect2, pindel, varscan2
- VWF | c.7081G>A p.A2361T | Missense Mutation (SNP) | VAF 67/253 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1396364240; called by muse, mutect2, varscan2
- WDR1 | c.943G>A p.V315I (on ENST00000382452; = p.V175I on NM_005112.5) | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as rs376548034; called by muse, varscan2
- WDR59 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.469); catalogued as rs765022631, COSV50941323; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 40/152 reads (26%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WNT5B | c.802A>G p.S268G | Missense Mutation (SNP) | VAF 48/375 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.232); catalogued as rs914841243; called by muse, mutect2, varscan2
- XPNPEP1 | c.1875C>T p.C625= | Splice Region (SNP) | VAF 29/115 reads (25%) | catalogued as rs763353960; called by muse, mutect2, varscan2
- YBX3 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs563667692; called by muse, mutect2, varscan2
- ZBTB20 | c.346C>T p.R116C (on ENST00000474710 / NM_001164342.2; = p.R43C on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 154/492 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61843423; called by mutect2, varscan2
- ZBTB21 | c.1888_1889dup p.I631Kfs*6 | Frame Shift Ins (INS) | VAF 50/178 reads (28%) | catalogued as rs769060928; called by mutect2, varscan2
- ZBTB8OS | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.881); catalogued as rs776311479, COSV59385812; called by muse, mutect2, varscan2
- ZC3H13 | c.3831_3833del p.R1277del | In Frame Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs747701957; called by pindel, varscan2
- ZC3H4 | c.394_396del p.S133del | In Frame Del (DEL) | VAF 22/86 reads (26%) | catalogued as rs1311051368; called by pindel, varscan2
- ZDBF2 | c.6886C>T p.R2296W | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs201914677; called by muse, mutect2, varscan2
- ZDHHC8 | c.1156G>T p.D386Y | Missense Mutation (SNP) | VAF 90/273 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV100272659; called by muse, mutect2, varscan2
- ZEB2 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 103/345 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs1206446041, COSV57958275; called by muse, mutect2, varscan2
- ZMYM1 | c.1658A>G p.Y553C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63252273; called by muse, mutect2, varscan2
- ZNF133 | c.1166G>A p.R389Q (on ENST00000316358 / NM_001352454.2; = p.R388Q on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/288 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.131); catalogued as rs1369582710, COSV60366659; called by muse, mutect2, varscan2
- ZNF184 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs768232376; called by muse, mutect2
- ZNF185 | c.1252G>A p.G418R | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs781800037, COSV59274942; called by muse, mutect2, varscan2
- ZNF212 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 88/369 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs763437708; called by muse, mutect2, varscan2
- ZNF311 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 114/367 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65853188; called by muse, mutect2, varscan2
- ZNF317 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 91/261 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs776581463; called by muse, varscan2
- ZNF331 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 73/229 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1349218941; called by muse, mutect2, varscan2
- ZNF467 | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV100118086; called by muse, mutect2, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 30/81 reads (37%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF541 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs368317942; called by muse, mutect2, varscan2
- ZNF572 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 83/250 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1167389823; called by muse, mutect2, varscan2
- ZNF71 | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 96/333 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.679); catalogued as COSV100045695; called by muse, mutect2, varscan2
- ZNF786 | c.2336C>T p.A779V | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1348669702, COSV60277532; called by muse, mutect2
- ZNF800 | c.1322del p.K441Rfs*61 | Frame Shift Del (DEL) | VAF 19/193 reads (10%) | catalogued as rs1346638445; called by mutect2, pindel
- ZNF814 | c.566_568del p.E189del | In Frame Del (DEL) | VAF 66/366 reads (18%) | catalogued as rs767232351; called by pindel, varscan2
- ZNRF3 | c.1577del p.T526Sfs*44 (on ENST00000544604 / NM_001206998.2; = p.T426Sfs*44 on NM_032173.3) | Frame Shift Del (DEL) | VAF 46/184 reads (25%) | catalogued as COSV60431850; called by mutect2, pindel, varscan2
- A3GALT2 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- AAR2 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 110/409 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ABCC5 | c.3688G>T p.G1230* | Nonsense Mutation (SNP) | VAF 17/103 reads (17%) | called by muse, mutect2, varscan2
- ACACA | c.2474T>C p.V825A | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- ACTA1 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ADAM10 | c.1066_1068del p.K356del | In Frame Del (DEL) | VAF 74/215 reads (34%) | called by pindel, varscan2
- ADAM15 | c.1661del p.G554Efs*50 | Frame Shift Del (DEL) | VAF 108/364 reads (30%) | called by mutect2, pindel, varscan2
- ADAMTS16 | c.2926T>C p.S976P | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRV1 | c.4424G>T p.R1475I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2
- ADGRV1 | c.6389C>A p.A2130E | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADO | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 93/294 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ADSL | c.728A>G p.Y243C | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AEBP1 | c.3077G>A p.R1026H | Missense Mutation (SNP) | VAF 101/378 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- AKAP1 | c.445dup p.L149Pfs*15 | Frame Shift Ins (INS) | VAF 76/280 reads (27%) | called by mutect2, pindel, varscan2
- AKAP12 | c.3965T>C p.L1322P | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- AMBN | c.1054G>T p.G352W | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMH | c.381del p.Q128Sfs*11 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- ANKRD20A1 | c.906del p.E303Rfs*18 | Frame Shift Del (DEL) | VAF 46/230 reads (20%) | called by mutect2, pindel, varscan2
- ANKRD55 | c.995A>G p.Q332R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ANKRD6 | c.1942G>A p.A648T (on ENST00000339746 / NM_001242809.2; = p.A643T on NM_014942.4) | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ANTXR1 | c.1236G>T p.K412N | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AP4B1 | c.196_198del p.K66del | In Frame Del (DEL) | VAF 122/417 reads (29%) | called by pindel, varscan2
- APBB2 | c.1532T>G p.F511C (on ENST00000295974 / NM_001166050.2; = p.F512C on NM_004307.2) | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APPBP2 | c.898A>G p.N300D | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- ARAP1 | c.680-1G>A p.X227_splice | Splice Site (SNP) | VAF 47/169 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP23 | c.2555del p.G852Afs*70 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- ARHGAP32 | c.2174C>T p.P725L (on ENST00000310343 / NM_001378025.1; = p.P376L on NM_014715.4) | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ARHGAP4 | c.1268G>A p.S423N | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ARHGAP5 | c.2828del p.N943Ifs*2 | Frame Shift Del (DEL) | VAF 39/131 reads (30%) | called by mutect2, varscan2
- ARHGEF26 | c.440del p.P147Rfs*19 | Frame Shift Del (DEL) | VAF 63/200 reads (32%) | called by mutect2, pindel, varscan2
- ARMH2 | c.124_128delinsG p.K42Efs*23 | Frame Shift Del (DEL) | VAF 10/109 reads (9%) | called by pindel, varscan2*
- ARRDC4 | c.912dup p.L305Ifs*15 | Frame Shift Ins (INS) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- ASTL | c.26C>A p.P9H | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- ATF7IP | c.959dup p.N320Kfs*4 | Frame Shift Ins (INS) | VAF 13/64 reads (20%) | called by mutect2, varscan2
- ATG2B | c.5424del p.F1808Lfs*28 | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | called by mutect2, pindel, varscan2
- ATXN2 | c.1657C>T p.P553S (on ENST00000550104; = p.P393S on NM_002973.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 130/438 reads (30%) | called by pindel, varscan2
- B2M | c.276dup p.T93Hfs*2 | Frame Shift Ins (INS) | VAF 102/398 reads (26%) | called by mutect2, pindel, varscan2
- BAAT | c.1152G>A p.W384* | Nonsense Mutation (SNP) | VAF 36/606 reads (6%) | called by muse, mutect2
- BCDIN3D | c.289T>C p.C97R | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- BLID | c.230T>C p.M77T | Missense Mutation (SNP) | VAF 90/308 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRINP1 | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 99/390 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BTBD10 | c.1086G>T p.R362S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- C2CD5 | c.2137C>A p.P713T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- C8B | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 149/494 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CACNA1B | c.5440C>T p.Q1814* | Nonsense Mutation (SNP) | VAF 71/286 reads (25%) | called by muse, mutect2, varscan2
- CAD | c.1043T>C p.L348P | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CADM1 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 134/447 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAMTA1 | c.1373C>T p.T458I | Missense Mutation (SNP) | VAF 121/407 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CASKIN1 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 64/236 reads (27%) | called by muse, mutect2, varscan2
- CCDC154 | c.982C>A p.Q328K | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- CCER2 | c.726G>T p.E242D | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); called by muse, mutect2
- CCR4 | c.278C>G p.P93R | Missense Mutation (SNP) | VAF 85/222 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK12 | c.3097C>A p.L1033I | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CEL | c.1728dup p.T577Hfs*3 (on ENST00000673714; = p.T574Hfs*3 on NM_001807.6) | Frame Shift Ins (INS) | VAF 53/277 reads (19%) | called by mutect2, pindel, varscan2
- CELSR3 | c.85dup p.L29Pfs*70 | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- CHCHD3 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- CIR1 | c.1300del p.M434Cfs*13 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- CKAP5 | c.876del p.K292Nfs*12 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, varscan2
- CMPK2 | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CNNM1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- CNNM2 | c.1531del p.L511* | Frame Shift Del (DEL) | VAF 82/327 reads (25%) | called by mutect2, pindel, varscan2
- CNTN6 | c.157A>G p.N53D | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, varscan2
- COLQ | c.1300T>G p.S434A | Missense Mutation (SNP) | VAF 49/267 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- COPE | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 66/223 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- COPS4 | c.284G>T p.R95I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CSMD3 | c.1156A>G p.T386A | Missense Mutation (SNP) | VAF 106/368 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CSPG4 | c.2245C>T p.Q749* | Nonsense Mutation (SNP) | VAF 83/269 reads (31%) | called by muse, mutect2, varscan2
- CTU1 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- CYP3A5 | c.1328G>A p.G443D | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DCANP1 | c.253del p.A85Qfs*89 | Frame Shift Del (DEL) | VAF 74/204 reads (36%) | called by mutect2, pindel, varscan2
- DDB1 | c.685del p.A229Pfs*74 | Frame Shift Del (DEL) | VAF 62/219 reads (28%) | called by mutect2, pindel, varscan2
- DENND2B | c.821G>A p.S274N | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DIO3 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 92/268 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DIS3L | c.905del p.N302Mfs*8 (on ENST00000319212 / NM_001143688.3; = p.N219Mfs*8 on NM_133375.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 39/137 reads (28%) | called by mutect2, pindel, varscan2
- DNAH11 | c.13240del p.T4414Qfs*72 | Frame Shift Del (DEL) | VAF 30/127 reads (24%) | called by mutect2, varscan2
- DNAH14 | c.5891dup p.N1964Kfs*21 (on ENST00000445597; = p.N2504Kfs*21 on NM_001367479.1) | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | called by mutect2, varscan2
- DROSHA | c.248del p.P83Hfs*25 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- DTX2 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DXO | c.1044-3del | Splice Region (DEL) | VAF 27/205 reads (13%) | called by mutect2, pindel, varscan2
- ECSIT | c.781del p.Q261Sfs*5 | Frame Shift Del (DEL) | VAF 87/336 reads (26%) | called by mutect2, varscan2
- EDF1 | c.130+1G>A p.X44_splice | Splice Site (SNP) | VAF 16/216 reads (7%) | called by muse, mutect2
- EGFR | c.3221C>T p.T1074I | Missense Mutation (SNP) | VAF 19/364 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2
- ELP2 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- ENTPD7 | c.388del p.I130Sfs*23 | Frame Shift Del (DEL) | VAF 28/92 reads (30%) | called by mutect2, pindel, varscan2
- ERF | c.1496del p.G499Afs*32 | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | called by mutect2, pindel, varscan2
- ERP27 | c.227A>G p.H76R | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- ETF1 | c.1125G>T p.L375F | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- EXD2 | c.1727T>C p.M576T (on ENST00000312994 / NM_001193362.1; = p.M451T on NM_018199.3) | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- EXOC3L2 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- EXOSC9 | c.234del p.F78Lfs*23 | Frame Shift Del (DEL) | VAF 46/124 reads (37%) | called by mutect2, varscan2
- FAM117A | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- FAM160A2 | c.2810A>T p.E937V (on ENST00000449352 / NM_001098794.2; = p.E951V on NM_032127.4) | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM166A | c.125T>G p.L42R | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FAM187A | c.1022del p.G341Afs*11 | Frame Shift Del (DEL) | VAF 37/317 reads (12%) | called by mutect2, pindel, varscan2
- FAM20C | c.456del p.G153Afs*34 | Frame Shift Del (DEL) | VAF 37/147 reads (25%) | called by mutect2, pindel, varscan2
- FAM71E2 | c.2044G>T p.G682C | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by mutect2, varscan2
- FBXW2 | c.685+2T>C p.X229_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- FER | c.548A>C p.N183T | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FGFR4 | c.1703del p.P568Qfs*53 | Frame Shift Del (DEL) | VAF 44/149 reads (30%) | called by mutect2, pindel, varscan2
- FIBCD1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- FIGNL2 | c.495del p.Y166Tfs*66 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- FJX1 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- FLRT2 | c.1214T>G p.L405R | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- FLT4 | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 28/583 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.011); called by muse, mutect2
- FRAT1 | c.155A>G p.Q52R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GAR1 | c.214+2T>C p.X72_splice | Splice Site (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- GID8 | c.160G>T p.G54* | Nonsense Mutation (SNP) | VAF 30/93 reads (32%) | called by muse, mutect2, varscan2
- GJA10 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 93/322 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNPTAB | c.1607G>T p.G536V | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPNMB | c.561G>T p.L187F | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR148 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 110/315 reads (35%) | called by muse, mutect2, varscan2
- GPR176 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GPR179 | c.1769C>T p.A590V (on ENST00000621958; = p.A589V on NM_001004334.4) | Missense Mutation (SNP) | VAF 57/213 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- GRM3 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 110/429 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- GZMA | c.88A>G p.I30V | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- HERC2 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (0.9); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- HNRNPL | c.1100del p.P367Hfs*28 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel
- HOMEZ | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 89/303 reads (29%) | called by muse, mutect2, varscan2
- HOXB1 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 50/225 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- HSFX2 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 122/207 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- HSPB6 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 93/287 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- HTR3A | c.804dup p.N269Qfs*25 | Frame Shift Ins (INS) | VAF 70/315 reads (22%) | called by mutect2, pindel, varscan2
- HUWE1 | c.12155_12157del p.G4052del | In Frame Del (DEL) | VAF 91/272 reads (33%) | called by mutect2, pindel, varscan2
- IDH3A | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- IFIH1 | c.55A>G p.R19G | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- IL12RB1 | c.250G>C p.G84R | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- IL17RC | c.653C>T p.A218V (on ENST00000295981 / NM_153461.4; = p.A147V on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- IRAK3 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 89/219 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ITGB1 | c.2251T>C p.W751R | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITPR1 | c.5329G>T p.G1777W (on ENST00000354582; = p.G1722W on NM_002222.7) | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- JAKMIP1 | c.1708A>T p.I570F | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- KANSL1 | c.1412_1415del p.K471Rfs*8 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | called by mutect2, pindel, varscan2
- KASH5 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- KAT6A | c.4055del p.L1352* | Frame Shift Del (DEL) | VAF 44/267 reads (16%) | called by mutect2, pindel, varscan2
- KCNB1 | c.2540del p.G847Efs*24 | Frame Shift Del (DEL) | VAF 10/110 reads (9%) | called by mutect2, pindel
- KCNC2 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2
- KCNH3 | c.422del p.G141Afs*67 | Frame Shift Del (DEL) | VAF 23/94 reads (24%) | called by mutect2, pindel, varscan2
- KCNS2 | c.779T>G p.L260R | Missense Mutation (SNP) | VAF 157/514 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KDM6B | c.2833G>A p.A945T | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1522 | c.1313C>A p.P438H (on ENST00000373480 / NM_001198972.2; = p.P497H on NM_020888.3) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- KIF1A | c.5072G>T p.R1691M (on ENST00000320389 / NM_001379639.1; = p.R1683M on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- KMT2B | c.4601del p.P1534Hfs*112 | Frame Shift Del (DEL) | VAF 35/240 reads (15%) | called by mutect2, pindel, varscan2
- KMT2C | c.11146_11147del p.E3716Rfs*8 | Frame Shift Del (DEL) | VAF 105/470 reads (22%) | called by mutect2, pindel, varscan2
- KMT2E | c.2619del p.K873Nfs*8 | Frame Shift Del (DEL) | VAF 18/107 reads (17%) | called by mutect2, pindel, varscan2
- LAS1L | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- LAX1 | c.650_651del p.F217Cfs*12 | Frame Shift Del (DEL) | VAF 68/293 reads (23%) | called by mutect2, pindel, varscan2
- LONRF1 | c.722A>C p.E241A | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRIF1 | c.1489del p.Y497Mfs*11 | Frame Shift Del (DEL) | VAF 54/194 reads (28%) | called by mutect2, pindel, varscan2
- LRP12 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- LRRC27 | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC37B | c.91G>T p.V31F | Missense Mutation (SNP) | VAF 68/234 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- LRRC40 | c.1619T>C p.M540T | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- LUZP1 | c.2238dup p.R747Qfs*7 | Frame Shift Ins (INS) | VAF 55/187 reads (29%) | called by mutect2, pindel, varscan2
- MAFA | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, varscan2
- MAGEB6B | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MAMLD1 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 89/297 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAN2A2 | c.2165T>C p.L722P | Missense Mutation (SNP) | VAF 37/345 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K2 | c.120del p.K40Nfs*29 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | called by mutect2, pindel, varscan2
- MDGA2 | c.177del p.W60Gfs*9 | Frame Shift Del (DEL) | VAF 10/113 reads (9%) | called by mutect2, pindel
- MED13L | c.6143_6147dup p.S2050Ifs*43 | Frame Shift Ins (INS) | VAF 88/290 reads (30%) | called by mutect2, varscan2
- MED23 | c.3112C>T p.R1038* | Nonsense Mutation (SNP) | VAF 100/295 reads (34%) | called by muse, mutect2, varscan2
- METTL6 | c.666del p.F222Lfs*19 | Frame Shift Del (DEL) | VAF 49/159 reads (31%) | called by mutect2, pindel, varscan2
- MGAT3 | c.164del p.P55Rfs*99 | Frame Shift Del (DEL) | VAF 60/175 reads (34%) | called by mutect2, pindel, varscan2
- MICAL2 | c.1298del p.P433Lfs*52 | Frame Shift Del (DEL) | VAF 31/125 reads (25%) | called by mutect2, pindel, varscan2
- MICAL2 | c.5018T>C p.L1673P | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MKI67 | c.3362A>G p.D1121G | Missense Mutation (SNP) | VAF 85/360 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MOV10L1 | c.2987A>C p.D996A | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- MRPS34 | c.561G>T p.E187D | Missense Mutation (SNP) | VAF 96/312 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MSX1 | c.485dup p.A163Sfs*12 | Frame Shift Ins (INS) | VAF 44/179 reads (25%) | called by mutect2, pindel, varscan2
- MYBL1 | c.1259del p.N420Tfs*13 | Frame Shift Del (DEL) | VAF 46/162 reads (28%) | called by mutect2, varscan2
- MYCBP2 | c.9988G>A p.A3330T (on ENST00000357337; = p.A3368T on NM_015057.5) | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYOCD | c.290T>G p.M97R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MYT1L | c.1711G>T p.G571* | Nonsense Mutation (SNP) | VAF 82/274 reads (30%) | called by muse, mutect2, varscan2
- NAV1 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NEK10 | c.1742A>G p.Q581R | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- NEU4 | c.380T>A p.V127E (on ENST00000391969 / NM_001167602.3; = p.V139E on NM_080741.4) | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NHS | c.848del p.L283* | Frame Shift Del (DEL) | VAF 64/198 reads (32%) | called by mutect2, varscan2
- NLRP7 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 122/432 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- NLRP7 | c.1044G>T p.E348D | Missense Mutation (SNP) | VAF 164/564 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0.007); called by mutect2, varscan2
- NOCT | c.1288C>A p.L430I | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); called by muse, mutect2
- NOMO1 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOTCH3 | c.6530dup p.P2178Tfs*64 | Frame Shift Ins (INS) | VAF 36/146 reads (25%) | called by mutect2, pindel, varscan2
- NOTUM | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.78); called by muse, varscan2
- NPAS3 | c.2503G>A p.E835K (on ENST00000356141 / NM_001164749.2; = p.E803K on NM_022123.3) | Missense Mutation (SNP) | VAF 129/379 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- NPAT | c.1642del p.S548Vfs*11 | Frame Shift Del (DEL) | VAF 19/180 reads (11%) | called by mutect2, pindel, varscan2
- NPFFR2 | c.1360C>T p.L454F | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NR2F1 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2
- NR3C1 | c.380C>A p.A127E | Missense Mutation (SNP) | VAF 117/409 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NRXN3 | c.899C>T p.A300V (on ENST00000557594 / NM_001272020.2; = p.A932V on NM_004796.6) | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NT5DC3 | c.1112_1113del p.Y371* | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by pindel, varscan2
- NUP210 | c.2284del p.Q762Sfs*44 | Frame Shift Del (DEL) | VAF 49/141 reads (35%) | called by mutect2, pindel, varscan2
- NUP37 | c.193del p.T65Hfs*14 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | called by mutect2, pindel, varscan2
- NUTM2F | c.1094G>T p.R365M | Missense Mutation (SNP) | VAF 64/490 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NVL | c.256del p.R86Gfs*34 | Frame Shift Del (DEL) | VAF 20/79 reads (25%) | called by mutect2, pindel, varscan2
- NXPH1 | c.564T>G p.D188E | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.06); called by muse, mutect2
- OR10J1 | c.371T>C p.V124A | Missense Mutation (SNP) | VAF 159/465 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- OR11H6 | c.972del p.L325* | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- OR2M3 | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 104/350 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- PAK1IP1 | c.939_942del p.P314Qfs*8 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel
- PAQR9 | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PARD3 | c.2189G>A p.S730N | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PATL1 | c.478del p.Q160Rfs*33 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | called by mutect2, pindel, varscan2
- PBXIP1 | c.1886C>A p.A629D | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- PCDH10 | c.973C>G p.Q325E | Missense Mutation (SNP) | VAF 104/333 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PCDH10 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 93/259 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCF11 | c.3716C>A p.P1239Q | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCLO | c.6776C>T p.A2259V | Missense Mutation (SNP) | VAF 64/270 reads (24%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCSK2 | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- PDZD8 | c.1039T>C p.C347R | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PEX6 | c.2312C>A p.P771Q | Missense Mutation (SNP) | VAF 147/483 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGAP6 | c.2176C>T p.H726Y | Missense Mutation (SNP) | VAF 109/344 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PHLPP1 | c.3557del p.N1186Tfs*10 | Frame Shift Del (DEL) | VAF 25/70 reads (36%) | called by mutect2, pindel, varscan2
- PHOSPHO2 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIAS1 | c.1276T>C p.S426P | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIGO | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 71/320 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- PLAGL2 | c.30del p.W11Gfs*15 | Frame Shift Del (DEL) | VAF 67/248 reads (27%) | called by mutect2, pindel, varscan2
- PLEC | c.1870G>T p.E624* (on ENST00000322810 / NM_201380.4; = p.E514* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 155/484 reads (32%) | called by muse, mutect2, varscan2
- PLXNA1 | c.3051del p.Q1019Rfs*22 | Frame Shift Del (DEL) | VAF 50/172 reads (29%) | called by mutect2, varscan2
- PLXNA3 | c.5452G>A p.A1818T | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PMPCB | c.650A>T p.N217I | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- POM121 | c.895C>T p.P299S (on ENST00000434423; = p.P34S on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); called by muse, mutect2
- POTEF | c.2491G>A p.A831T | Missense Mutation (SNP) | VAF 211/819 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- PPOX | c.471+8T>C | Splice Region (SNP) | VAF 50/335 reads (15%) | called by muse, mutect2, varscan2
- PPP1R26 | c.2310del p.S771Vfs*10 | Frame Shift Del (DEL) | VAF 44/181 reads (24%) | called by mutect2, pindel, varscan2
- PPP2R5E | c.35A>G p.D12G | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRKAG2 | c.371G>A p.S124N | Missense Mutation (SNP) | VAF 119/481 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PROKR2 | c.878G>A p.G293D | Missense Mutation (SNP) | VAF 212/692 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- PROSER1 | c.1657del p.L553* | Frame Shift Del (DEL) | VAF 54/257 reads (21%) | called by mutect2, pindel, varscan2
- PRR32 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- PRRC2A | c.4434G>T p.Q1478H | Missense Mutation (SNP) | VAF 103/296 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- PSMC1 | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSME2 | c.231+5G>T | Splice Region (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- PTGER3 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 155/449 reads (35%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- PTPN21 | c.1485G>T p.E495D | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTPRT | c.1106del p.G369Vfs*28 | Frame Shift Del (DEL) | VAF 33/151 reads (22%) | called by mutect2, pindel, varscan2
- PWWP3A | c.92dup p.N31Kfs*2 (on ENST00000627377; = p.N30Kfs*2 on NM_032853.5 and 7 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 22/78 reads (28%) | called by mutect2, pindel, varscan2
- PYGB | c.2438C>A p.S813Y | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RALGPS2 | c.1248G>A p.R416= | Splice Region (SNP) | VAF 31/106 reads (29%) | called by muse, mutect2, varscan2
- RASGRP1 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RASGRP3 | c.873dup p.A292Cfs*48 | Frame Shift Ins (INS) | VAF 64/229 reads (28%) | called by mutect2, pindel, varscan2
- RBBP6 | c.5263G>A p.V1755M | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, varscan2
- RBM12B | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- RDH10 | c.167T>C p.F56S | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RDH10 | c.923T>A p.V308D | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, varscan2
- RFFL | c.429_431del p.E143del | In Frame Del (DEL) | VAF 38/126 reads (30%) | called by pindel, varscan2
- RGL2 | c.257dup p.R87Tfs*27 | Frame Shift Ins (INS) | VAF 61/200 reads (31%) | called by mutect2, pindel, varscan2
- RGS12 | c.1454dup p.F486Ifs*2 | Frame Shift Ins (INS) | VAF 19/89 reads (21%) | called by mutect2, pindel, varscan2
- RP1 | c.1375_1376del p.Q459Kfs*13 | Frame Shift Del (DEL) | VAF 120/380 reads (32%) | called by mutect2, pindel, varscan2
- RPS6KA1 | c.1263G>T p.K421N | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- RRP1B | c.1339G>T p.G447C | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- RTEL1 | c.3241G>A p.A1081T | Missense Mutation (SNP) | VAF 41/334 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SALL3 | c.2767G>T p.G923C | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SCML2 | c.1608A>C p.K536N | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- SCRIB | c.643-6C>A | Splice Region (SNP) | VAF 147/393 reads (37%) | called by muse, mutect2, varscan2
- SEL1L3 | c.391del p.R131Gfs*15 | Frame Shift Del (DEL) | VAF 67/222 reads (30%) | called by mutect2, varscan2
- SEMA3C | c.1696G>T p.G566* | Nonsense Mutation (SNP) | VAF 42/174 reads (24%) | called by muse, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | called by mutect2, varscan2
- SETD1B | c.2079_2080del p.P694Tfs*147 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | called by mutect2, pindel
- SGCZ | c.399del p.Q134Sfs*2 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel, varscan2
- SH2D7 | c.56A>G p.D19G | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHFL | c.540del p.V181Cfs*75 | Frame Shift Del (DEL) | VAF 8/95 reads (8%) | called by mutect2, pindel
- SKOR2 | c.2217A>C p.E739D | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- SLC25A52 | c.371G>A p.R124H (on ENST00000672005; = p.R114H on NM_001034172.4) | Missense Mutation (SNP) | VAF 107/389 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC35A5 | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC35F6 | c.14dup p.Y6Vfs*93 | Frame Shift Ins (INS) | VAF 25/76 reads (33%) | called by mutect2, pindel, varscan2
- SLC38A9 | c.53A>G p.H18R | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9A7 | c.914A>G p.Y305C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- SMARCD2 | c.629A>T p.D210V | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SPATA25 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SPEG | c.5702del p.P1901Qfs*6 | Frame Shift Del (DEL) | VAF 54/203 reads (27%) | called by mutect2, pindel, varscan2
- SPTB | c.4309del p.E1437Sfs*18 | Frame Shift Del (DEL) | VAF 164/560 reads (29%) | called by mutect2, pindel, varscan2
- SQSTM1 | c.207T>C p.D69= | Splice Region (SNP) | VAF 32/562 reads (6%) | called by muse, mutect2
- STAG2 | c.3455C>A p.P1152H | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAT5B | c.1749del p.K583Nfs*16 | Frame Shift Del (DEL) | VAF 120/399 reads (30%) | called by mutect2, pindel, varscan2
- SYCE1 | c.11G>T p.R4M | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- SYT9 | c.1222del p.T408Hfs*8 | Frame Shift Del (DEL) | VAF 29/119 reads (24%) | called by mutect2, pindel, varscan2
- TACC3 | c.1410G>T p.E470D | Missense Mutation (SNP) | VAF 57/332 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAS2R38 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 89/418 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TBC1D16 | c.1813C>T p.L605F | Missense Mutation (SNP) | VAF 71/233 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TBC1D31 | c.579del p.F193Lfs*30 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- TESMIN | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TFAP2B | c.321del p.Q108Nfs*83 | Frame Shift Del (DEL) | VAF 147/509 reads (29%) | called by mutect2, pindel, varscan2
- TFAP2B | c.673A>G p.N225D | Missense Mutation (SNP) | VAF 94/287 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TFAP4 | c.761del p.G254Afs*45 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | called by mutect2, pindel, varscan2
- THADA | c.1708A>G p.T570A | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- THSD7A | c.1452dup p.A485Sfs*16 | Frame Shift Ins (INS) | VAF 14/93 reads (15%) | called by mutect2, pindel, varscan2
- TINAGL1 | c.314G>C p.C105S | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMCC3 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 75/259 reads (29%) | called by muse, mutect2, varscan2
- TMEM130 | c.1279T>C p.Y427H (on ENST00000416379 / NM_001134450.2; = p.Y415H on NM_152913.3) | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM132C | c.2393A>G p.K798R | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); called by muse, mutect2
- TMEM178B | c.773del p.G258Afs*14 | Frame Shift Del (DEL) | VAF 48/200 reads (24%) | called by mutect2, pindel, varscan2
- TMEM240 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM94 | c.3333C>A p.C1111* | Nonsense Mutation (SNP) | VAF 14/203 reads (7%) | called by muse, mutect2
- TNRC18 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- TOP2A | c.4424A>G p.D1475G | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, varscan2
- TP53BP2 | c.594del p.V199* (on ENST00000343537 / NM_001031685.3; = p.V70* on NM_005426.2) | Frame Shift Del (DEL) | VAF 32/128 reads (25%) | called by mutect2, varscan2
396 further variants in this file (35 protein-altering or splice-affecting, 227 silent, 134 other) are not listed here.
